Gene-level copy-number profile of tumor specimen TCGA-42-2591-01A from TCGA case TCGA-42-2591, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 51.1 years (18,654 days).
Specimen TCGA-42-2591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.66d09ec6-b2a5-49ae-ad0c-ebf8a7e61112.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-42-2591-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32e14172-9006-4f8d-bc5f-3c0383e555cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 22,400; copy number 2: 29,691; copy number 3: 6,482; copy number 4: 1,215; copy number 5: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-42-2591-01A-01D-1043-01): tumor purity 0.91, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:135,315,418–136,395,471, 11 genes: U6, KRT18P54, TARS2P1, AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3.
- chr4:138,819,954–139,012,646, 2 genes (within-gene range 0–2): AC109927.1, AC109927.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:136,553,236–136,553,739, 1 gene, copy number 5: AC093875.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 5: AC139365.2, AC139365.1.

Autosomal genes at a single copy (total copy number 1): 22,051. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
